Somatic mutation profile of tumor specimen 0DKSZD from CCDI case PBBYTK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.8 years (3,568 days).
Specimen 0DKSZD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4959ff3-57ff-404a-bb67-9d5767a8f408.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKSTW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5d5c2bc-3d88-4cf9-8679-b4b843273db5

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 8, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELF1 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 23/513 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV60114360; called by muse, mutect2
- KAZN | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 128/613 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs111675679; called by muse, mutect2, varscan2
- KIF4B | c.3640C>T p.R1214* | Nonsense Mutation (SNP) | VAF 334/753 reads (44%) | catalogued as rs371911920; called by muse, mutect2, varscan2
- VCAN | c.3743T>C p.M1248T | Missense Mutation (SNP) | VAF 116/700 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV54118423; called by muse, mutect2, varscan2
- B3GALNT2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 226/477 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CREBBP | c.3313G>A p.D1105N | Missense Mutation (SNP) | VAF 264/634 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CREBBP | c.1524_1530dup p.Q511Tfs*19 | Frame Shift Ins (INS) | VAF 278/667 reads (42%) | called by mutect2, varscan2
- PLA2R1 | c.1499T>A p.I500N | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- POTEJ | c.943G>C p.V315L | Missense Mutation (SNP) | VAF 75/430 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.06); called by muse, mutect2
- PPP4R3A | c.1239G>T p.K413N (on ENST00000554943 / NM_001366432.1; = p.K174N on NM_001284281.1) | Missense Mutation (SNP) | VAF 52/345 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM132D | c.2608A>C p.S870R | Missense Mutation (SNP) | VAF 207/508 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ADAD2 | c.234G>T p.L78= | Silent (SNP) | VAF 28/690 reads (4%) | called by muse, mutect2
- C4orf54 | c.2646C>T p.S882= | Silent (SNP) | VAF 24/620 reads (4%) | catalogued as rs1045437568, COSV72767086; called by muse, mutect2
- PKD1L1 | c.1263C>T p.N421= | Silent (SNP) | VAF 72/582 reads (12%) | catalogued as rs373313480; called by muse, mutect2, varscan2
- PLA2R1 | c.1500T>A p.I500= | Silent (SNP) | VAF 16/452 reads (4%) | called by muse, mutect2
- PRLR | c.222A>G p.E74= | Silent (SNP) | VAF 14/512 reads (3%) | called by muse, mutect2
- SIPA1L3 | c.3993C>T p.P1331= | Silent (SNP) | VAF 72/802 reads (9%) | catalogued as rs113677218; called by muse, mutect2
- TBX18 | c.1152C>A p.A384= | Silent (SNP) | VAF 448/1018 reads (44%) | called by muse, varscan2
- VPS33A | c.1083C>T p.I361= | Silent (SNP) | VAF 34/286 reads (12%) | catalogued as COSV99931196; called by muse, mutect2, varscan2
- KIFC3 | c.316-2636G>A | Intron (SNP) | VAF 18/324 reads (6%) | catalogued as rs782041004; called by muse, mutect2
- NLE1 | c.-4C>T | 5'UTR (SNP) | VAF 32/1164 reads (3%) | called by muse, mutect2
